Gene-level copy-number profile of tumor specimen TCGA-ZF-AA53-01A from TCGA case TCGA-ZF-AA53, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 60.3 years (22,035 days).
Specimen TCGA-ZF-AA53-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.d28cffeb-3f0b-4dc9-9ae6-43510e15bdd8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-AA53-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b1a7cdfc-5ed0-49ae-9ec8-770fccf67df3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 1,615; copy number 2: 15,219; copy number 3: 30,416; copy number 4: 8,867; copy number 5: 2,520; copy number 6: 191; copy number 7: 512; copy number 9: 43; copy number 10: 40; copy number 11: 2; copy number 12: 72; copy number 13: 12; copy number 15: 9; copy number 17: 2; copy number 19: 18; copy number 20: 125; copy number 23: 13; copy number 26: 68; copy number 36: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-AA53-01A-11D-A390-01): tumor purity 0.22, ploidy 3.51, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–23,438,700, 65 genes (within-gene range 0–4) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 921 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:96,593,170–97,060,415, 23 genes, copy number 10: KANSL3, FER1L5, LMAN2L, CNNM4, MIR3127, CNNM3-DT, CNNM3, ANKRD23, ANKRD39, SEMA4C, FAM178B, AC092636.1, Metazoa_SRP, RNA5SP101, AC079395.3, AC079395.2, AC079395.1, TRIM43CP, AC018892.1, AC018892.2, IGKV2OR2-1, IGKV2OR2-2, IGKV1OR2-3.
- chr4:64,275,257–64,433,215, 3 genes, copy number 10: TECRL, RNU6-191P, DPP3P1.
- chr6:9,596,110–12,319,592, 59 genes, copy number 23–36 (within-gene range 2–36): OFCC1, AL136226.1, AL354868.1, RNU6ATAC21P, AL138885.1, TFAP2A, TFAP2A-AS2, TFAP2A-AS1, AL138885.2, AL138885.3, LINC00518, MIR5689HG, MIR5689, MRPL48P1, LINC02522, GCNT2, AL139039.3, AL139039.1, AL139039.2, GCNT2P1, AL358777.3, C6orf52, Y_RNA, PAK1IP1, TMEM14C, AL024498.1, TMEM14B, AL024498.2, RNA5SP203, MAK, GCM2, AL357497.1, SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3, AL022724.2, AMD1P4, AL157373.1, AL157373.2, HIVEP1, EDN1, SUMO2P12.
- chr6:40,713,411–46,606,162, 168 genes, copy number 9–20 (within-gene range 6–20) (broad region; genes not listed).
- chr6:50,411,844–50,773,033, 4 genes, copy number 10: AL132799.1, AL360175.1, AL135908.1, TFAP2D.
- chr6:55,939,790–56,394,094, 2 genes, copy number 11 (within-gene range 4–11): NPM1P36, COL21A1.
- chr8:32,256,496–32,448,803, 2 genes, copy number 17: RNA5SP263, NRG1-IT3.
- chr8:35,862,123–38,704,855, 72 genes, copy number 12 (broad region; genes not listed).
- chr8:49,740,216–51,015,165, 9 genes, copy number 15: PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1.
- chr10:42,149,310–43,138,334, 32 genes, copy number 7: KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1, CCNYL2, AL391099.1, LINC00839, ZNF37BP, FXYD6P1, EIF3LP2, ZNF33B, AL022345.3, AL022345.1, AL022345.2, RNU6-1170P, AL022345.4, LINC01518, VN1R54P, CUBNP1, LINC02632, RSU1P1, DUXAP3, AL022344.1, BMS1, RNU6-885P, LINC02623, LINC01264, MIR5100, RET, AC010864.1.
- chr11:68,980,021–71,252,577, 57 genes, copy number 13–26 (within-gene range 13–57): MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr16:70,114,332–73,891,871, 104 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 7 (broad region; genes not listed).
- chr20:8,831,186–9,839,076, 10 genes, copy number 10 (within-gene range 4–10): RNU105B, AL445567.1, AL445567.2, Metazoa_SRP, PLCB4, LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1.

Autosomal genes at a single copy (total copy number 1): 1,606. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
